Gene-level copy-number profile of tumor specimen TCGA-EJ-7328-01A from TCGA case TCGA-EJ-7328, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.5 years (25,756 days).
Specimen TCGA-EJ-7328-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.370a1c0f-78d2-4330-a6fb-f644064b8ed7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-7328-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c4784f22-5424-48c8-aa35-ba2cdfc0496a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,207; copy number 2: 54,307; copy number 3: 15; copy number 9: 288.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-7328-01A-31D-2112-01): tumor purity 0.42, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 288 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:19,878,555–25,581,122, 287 genes, copy number 9 (broad region; genes not listed).
- chr15:25,738,508–25,738,620, 1 gene, copy number 9: RNA5SP390.

Autosomal genes at a single copy (total copy number 1): 2,827. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
